Somatic mutation profile of tumor specimen ALCH-B21T-TTP1-A (aliquot ALCH-B21T-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B21T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.6 years (23,590 days).
Specimen ALCH-B21T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b324eaa-2d22-4726-b88d-1ba3c19f1e32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B21T-NB1-A (Blood Derived Normal), aliquot ALCH-B21T-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd023fc2-b680-4c17-8060-d78d8a61601d

The open-access MAF lists 520 somatic variants for this specimen: 360 protein-altering or splice-affecting, 110 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 321, Silent 110, Intron 26, Nonsense Mutation 23, RNA 12, Splice Site 11, 3'UTR 7, 3'Flank 3, Splice Region 3, 5'Flank 2, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1810T>C p.C604R | Missense Mutation (SNP) | VAF 14/240 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55888333; called by muse, mutect2
- ACKR1 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV63674917; called by muse, mutect2, varscan2
- ADAMTSL3 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 35/487 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774772996, COSV54438263; called by muse, mutect2
- AK4 | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV59196519, COSV59198835; called by muse, mutect2
- AL121899.2 | c.1094C>A p.S365* | Nonsense Mutation (SNP) | VAF 22/296 reads (7%) | catalogued as rs763641265, COSV67350084; called by muse, mutect2
- ASPM | c.7188G>T p.R2396S | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99659386; called by muse, mutect2
- ASPM | c.3604A>G p.T1202A | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54123731; called by muse, mutect2
- ATF6 | c.1400G>A p.C467Y | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63409748; called by muse, mutect2
- ATP2B3 | c.1444C>G p.R482G | Missense Mutation (SNP) | VAF 19/391 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54845281; called by muse, mutect2
- ATP2B3 | c.2087G>T p.R696L | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs782459941, COSV54840389; called by muse, mutect2
- ATRX | c.6829G>T p.E2277* | Nonsense Mutation (SNP) | VAF 17/402 reads (4%) | catalogued as COSV64871445, COSV64875814, COSV64883974; called by muse, mutect2
- AVPR2 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61686229; called by muse, mutect2
- BEND2 | c.1289-2A>G p.X430_splice | Splice Site (SNP) | VAF 8/128 reads (6%) | catalogued as rs903034442; called by muse, mutect2
- BTN2A2 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1370809705, COSV100760256; called by muse, mutect2, varscan2
- CASP8AP2 | c.5631G>T p.K1877N | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.663); catalogued as rs1400211137; called by muse, mutect2
- CCDC138 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs1229774000; called by muse, mutect2, varscan2
- CD1C | c.796G>C p.V266L | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs1463015334; called by muse, mutect2
- CDH8 | c.857C>A p.P286Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as COSV54880485; called by muse, varscan2
- CDYL2 | c.1419C>A p.D473E | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV73653979; called by muse, mutect2
- CFAP44 | c.2584A>G p.K862E | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs868078362; called by muse, mutect2
- CHRNA6 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as rs765736119; called by muse, mutect2, varscan2
- CORO2B | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55952983, COSV99963528; called by muse, mutect2
- CRISP3 | c.399G>A p.M133I (on ENST00000371159 / NM_001368123.1; = p.M115I on NM_006061.4) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV53822465; called by muse, mutect2, varscan2
- CSMD1 | c.7160C>T p.P2387L (on ENST00000520002; = p.P2386L on NM_033225.6) | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1440723379; called by muse, mutect2
- CTNNA2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV100786054; called by muse, mutect2
- CTNNA2 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100785271; called by muse, mutect2
- DBX2 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 17/285 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs201941605; called by muse, mutect2
- ELMOD1 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs897645813; called by muse, mutect2
- FAM135B | c.3823G>A p.G1275R | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374711628; called by muse, mutect2
- FAM47B | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 15/308 reads (5%) | catalogued as COSV100263974; called by muse, mutect2
- FAM90A1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 30/500 reads (6%) | catalogued as COSV56710170; called by muse, mutect2
- FAT1 | c.11218G>T p.G3740* | Nonsense Mutation (SNP) | VAF 24/520 reads (5%) | catalogued as COSV71675681; called by muse, mutect2
- FPR2 | c.712C>A p.R238S | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs866790761, COSV60674585; called by muse, mutect2
- GPR15 | c.166G>C p.G56R | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as rs1402699180, COSV99423830; called by muse, mutect2
- H2AC1 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51237038; called by muse, mutect2, varscan2
- H2AC20 | c.371A>T p.H124L | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV58611289; called by muse, mutect2
- HIVEP1 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs757813686; called by muse, mutect2, varscan2
- HMGCLL1 | c.785T>C p.M262T | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51451617; called by muse, mutect2
- ICA1L | c.867-1G>T p.X289_splice | Splice Site (SNP) | VAF 16/213 reads (8%) | catalogued as COSV64172708; called by muse, mutect2
- ICE1 | c.3085G>T p.G1029C | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs757865822, COSV56828708; called by muse, mutect2
- IGHV2-26 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs564082269; called by muse, mutect2, varscan2
- IL6R | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59817662; called by muse, mutect2
- INTS5 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs1323777859; called by muse, mutect2
- KCNJ3 | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 23/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54546077; called by muse, mutect2
- KCNU1 | c.2360A>G p.H787R | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1487321522, COSV67759375; called by muse, mutect2, varscan2
- KLRG2 | c.1109+2T>A p.X370_splice | Splice Site (SNP) | VAF 8/94 reads (9%) | catalogued as rs1275262561; called by muse, mutect2
- LHX1 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1455121227; called by muse, mutect2
- LILRA4 | c.1474G>C p.V492L | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.893); catalogued as rs374334897; called by muse, mutect2
- LNX1 | c.931G>T p.V311L (on ENST00000263925 / NM_001126328.3; = p.V215L on NM_032622.2) | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.211); catalogued as rs374448115; called by muse, mutect2
- MPO | c.1409C>A p.T470K | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1283057698; called by muse, mutect2, varscan2
- MS4A14 | c.1192C>A p.Q398K | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV55733538; called by muse, mutect2
- MSX2 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99497003; called by muse, mutect2
- MT1E | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV57841745; called by muse, mutect2
- MXRA5 | c.1309A>C p.I437L | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV54229745; called by muse, mutect2
- MYH8 | c.3769G>T p.D1257Y | Missense Mutation (SNP) | VAF 35/663 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67963242; called by muse, mutect2
- MYO3A | c.2717G>T p.G906V | Missense Mutation (SNP) | VAF 34/580 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.042); catalogued as COSV99779102; called by muse, mutect2
- NAP1L3 | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100220152, COSV100220538; called by muse, varscan2
- NECAP1 | c.417A>C p.E139D | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as rs778506326; called by muse, mutect2
- NGFR | c.1150C>A p.R384S | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs1400123877; called by muse, mutect2, varscan2
- NPAS4 | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60650791; called by muse, mutect2
- OBSCN | c.11291G>T p.G3764V | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52741264, COSV52851349; called by muse, mutect2, varscan2
- OR10A4 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1459813235; called by muse, mutect2
- OR10G3 | c.833C>A p.T278K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs948686591; called by muse, mutect2
- OR10K1 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 18/549 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV56873963; called by muse, mutect2
- OR2L3 | c.712C>A p.L238M | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63454600; called by muse, mutect2, varscan2
- OR2M7 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV58738236, COSV58739311; called by muse, mutect2
- OR52B4 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68768633; called by muse, mutect2
- OR5B12 | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 11/146 reads (8%) | catalogued as COSV100222529; called by muse, mutect2
- OR8D4 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391223487; called by muse, mutect2
- OR8H3 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs552568669, COSV100539187; called by muse, mutect2
- OR8K5 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV57888782; called by muse, mutect2
- OXCT1 | c.1402C>G p.R468G | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as CM111021; called by muse, mutect2
- PABPC4L | c.1094C>A p.A365D | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1201285897; called by muse, mutect2
- PARP8 | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99892730; called by muse, mutect2
- PCDH11X | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1306422379; called by muse, mutect2
- PCDHGB4 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as rs1242973473, COSV54036019, COSV99544123; called by muse, mutect2
- PDE10A | c.2194G>T p.A732S | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100605347; called by muse, mutect2
- PEG3 | c.3537C>A p.F1179L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV55634145, COSV99689718; called by muse, mutect2, varscan2
- PLA1A | c.966G>T p.K322N | Missense Mutation (SNP) | VAF 31/379 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV56331736; called by muse, mutect2
- PPP1R12B | c.2451G>T p.E817D | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV51789229; called by muse, mutect2, varscan2
- PREX2 | c.3718G>C p.V1240L | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV55772059; called by muse, mutect2
- PRSS3 | c.260C>A p.S87Y (on ENST00000361005 / NM_007343.4; = p.S195Y on NM_002771.3) | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100725686; called by muse, mutect2
- PTPRD | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 24/350 reads (7%) | catalogued as COSV100645486; called by muse, mutect2
- PTPRQ | c.2750G>T p.W917L (on ENST00000616559; = p.W875L on NM_001145026.2) | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57040203; called by muse, mutect2
- RBP7 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV53812605; called by muse, mutect2
- RSPRY1 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs768296692; called by muse, mutect2
- RXFP1 | c.40G>T p.G14* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV57049653; called by muse, mutect2
- SETBP1 | c.3502G>T p.D1168Y | Missense Mutation (SNP) | VAF 20/587 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99953304; called by muse, mutect2
- SHISA7 | c.638C>A p.A213E | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1187152327; called by muse, mutect2
- SLC22A18 | c.1163A>T p.Y388F | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.402); catalogued as rs1316224684; called by muse, mutect2
- SLC4A4 | c.2806C>A p.Q936K (on ENST00000264485 / NM_001098484.3; = p.Q892K on NM_003759.4) | Missense Mutation (SNP) | VAF 38/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99140481; called by muse, mutect2
- SORCS3 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100865782, COSV63803647; called by muse, mutect2
- SPTA1 | c.4918G>A p.A1640T | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs1272797952; called by muse, mutect2
- ST6GAL2 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | PolyPhen benign (0.01); catalogued as COSV64527288, COSV64528515; called by muse, mutect2, varscan2
- STXBP5L | c.2562C>A p.F854L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as COSV56510452; called by muse, mutect2
- SULF2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs116302994; called by muse, mutect2
- TBX15 | c.713A>T p.H238L (on ENST00000369429 / NM_001330677.2; = p.H132L on NM_152380.3) | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs769942045; called by muse, mutect2
- THEMIS | c.1037C>A p.P346Q | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370867739; called by muse, mutect2
- TMC7 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs150991752, COSV99076143; called by muse, mutect2
- TMEM132C | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV70657367; called by muse, mutect2
- TMEM134 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1452075916; called by muse, mutect2
- TRPA1 | c.1269G>T p.Q423H | Missense Mutation (SNP) | VAF 36/546 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100084153, COSV51569164; called by muse, mutect2
- TUBA3C | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs748296492, COSV101262790; called by muse, mutect2
- TYR | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 27/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD153203, COSV54479390, COSV99635617; called by muse, mutect2
- UNC79 | c.233C>G p.P78R | Missense Mutation (SNP) | VAF 21/379 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56384187; called by muse, mutect2
- VAV3 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58386060; called by muse, mutect2
- VGF | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV50800836; called by muse, mutect2
- VSX1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs1011464814; called by muse, mutect2, varscan2
- ZNF280A | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV57481919; called by muse, mutect2
- ZNF331 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV53476488; called by muse, mutect2
- ZNF496 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.264); catalogued as rs914504638; called by muse, mutect2, varscan2
- ZSCAN23 | c.1170G>T p.*390Yext*8 | Nonstop Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99231834; called by muse, mutect2, varscan2
- AADACL2 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ABCG8 | c.356C>A p.T119N | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AC023469.1 | n.217G>T | Splice Region (SNP) | VAF 29/246 reads (12%) | called by muse, mutect2, varscan2
- ACMSD | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2
- ADAM18 | c.108T>A p.N36K | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ADAMTS12 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADRA1B | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ALDH16A1 | c.489G>C p.W163C | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ANO1 | c.2886C>A p.H962Q | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- ANO4 | c.1130C>A p.T377N (on ENST00000392977 / NM_001286615.2; = p.T342N on NM_178826.4) | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.433); called by muse, mutect2
- AP3B2 | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- APBB2 | c.2023A>T p.T675S (on ENST00000295974 / NM_001166050.2; = p.T676S on NM_004307.2) | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by muse, mutect2
- ARHGAP31 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 10/306 reads (3%) | called by muse, mutect2
- ATP11A | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 29/430 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ATP2B2 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATR | c.4064G>A p.G1355E | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATXN3 | c.784A>G p.R262G | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- AZGP1 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- B3GALT2 | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.1); called by muse, mutect2
- BBS9 | c.1329+1G>T p.X443_splice | Splice Site (SNP) | VAF 46/644 reads (7%) | called by muse, mutect2
- BCAS1 | c.1604C>A p.S535* | Nonsense Mutation (SNP) | VAF 18/458 reads (4%) | called by muse, mutect2
- BCDIN3D | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.162); called by muse, mutect2
- BUD23 | c.48+1G>T p.X16_splice | Splice Site (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- C2CD2 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 8/230 reads (3%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.601); called by muse, mutect2
- C2CD5 | c.957G>T p.M319I | Missense Mutation (SNP) | VAF 21/442 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.339); called by muse, mutect2
- C2CD5 | c.601+1G>T p.X201_splice | Splice Site (SNP) | VAF 10/318 reads (3%) | called by muse, mutect2
- CABCOCO1 | c.71-2A>T p.X24_splice | Splice Site (SNP) | VAF 22/372 reads (6%) | called by muse, mutect2
- CARMIL2 | c.3352G>T p.E1118* | Nonsense Mutation (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- CCM2 | c.341G>C p.S114T | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCNJL | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- CDADC1 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CDC73 | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 43/458 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CDH12 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CEP170 | c.3352G>A p.D1118N | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- CEP295 | c.3946T>G p.F1316V | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- CFAP74 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- CFHR3 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.348); called by muse, mutect2
- CHD8 | c.4324G>T p.G1442W (on ENST00000646647 / NM_001170629.2; = p.G1163W on NM_020920.4) | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- CHD9 | c.943A>G p.R315G | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.011); called by muse, mutect2
- CHM | c.1444C>G p.P482A | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2
- CHP2 | c.339G>C p.R113S | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLTCL1 | c.1688C>G p.T563S | Missense Mutation (SNP) | VAF 9/260 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP2 | c.3641G>T p.C1214F | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL11A1 | c.4445C>A p.P1482Q | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.327); called by muse, mutect2
- COL11A1 | c.2551C>A p.P851T | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL6A6 | c.3223G>T p.G1075* | Nonsense Mutation (SNP) | VAF 18/470 reads (4%) | called by muse, mutect2
- COL9A1 | c.2297G>T p.C766F | Missense Mutation (SNP) | VAF 33/714 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CPS1 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPS1 | c.2296C>A p.L766M | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNNA3 | c.2070G>C p.E690D | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CYP3A7 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 16/516 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2
- DACH2 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.237); called by muse, mutect2
- DAGLA | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- DCDC1 | c.4841C>A p.T1614N (on ENST00000597505 / NM_001367979.1; = p.T721N on NM_020869.3) | Missense Mutation (SNP) | VAF 32/395 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2
- DIO2 | c.451T>A p.S151T | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); called by muse, mutect2
- DLG3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.054); called by muse, mutect2
- DLST | c.635A>T p.E212V | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- DNAH12 | c.4286C>T p.A1429V (on ENST00000351747; = p.A1452V on NM_001366028.2) | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH8 | c.4296G>T p.K1432N | Missense Mutation (SNP) | VAF 74/544 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAJC6 | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DOCK11 | c.5687C>T p.P1896L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DPRX | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EIF4G3 | c.2727C>G p.I909M | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ELOA2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.637); called by muse, mutect2
- ERBB4 | c.2499C>A p.Y833* | Nonsense Mutation (SNP) | VAF 11/187 reads (6%) | called by muse, mutect2
- ERC1 | c.3179G>T p.W1060L (on ENST00000360905 / NM_178040.4; = p.W1032L on NM_178039.4) | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- EVC2 | c.2238G>T p.K746N | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- EXOC6B | c.1990G>T p.A664S | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- FAM72A | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.4010C>A p.P1337Q | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FAT3 | c.8609G>T p.S2870I | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2
- FBXL7 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2
- FBXO7 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 15/543 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- FER1L5 | c.3866C>A p.P1289H (on ENST00000623019; = p.P1262H on NM_001293083.2) | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FLG | c.7516G>T p.G2506W | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- FLNA | c.3208-1G>T p.X1070_splice | Splice Site (SNP) | VAF 9/165 reads (5%) | called by muse, mutect2
- FLRT2 | c.16A>T p.T6S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- FMN1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2
- FMN2 | c.2011G>T p.G671* | Nonsense Mutation (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2, varscan2
- FSIP2 | c.4709C>A p.T1570K | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- GBE1 | c.1032G>T p.W344C | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GP2 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2
- GPR50 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.339); called by muse, mutect2
- GRIK3 | c.1798G>T p.G600C | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- GRIN2A | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 40/473 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.891); called by muse, mutect2
- GRIN2B | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- HCN1 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 79/807 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- HCN1 | c.283C>G p.Q95E | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2
- HEPH | c.2773T>A p.F925I (on ENST00000343002; = p.F658I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/429 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HOXC13 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- IGSF1 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- IGSF11 | c.215A>T p.Q72L (on ENST00000393775 / NM_001015887.3; = p.Q71L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2
- IGSF5 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- IHH | c.1174G>T p.G392W | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL21R | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- INPP5D | c.3025C>A p.L1009M (on ENST00000445964 / NM_001017915.3; = p.L1008M on NM_005541.5) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.201); called by muse, mutect2
- IRS4 | c.2447G>T p.R816L | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- JAG2 | c.2479+3G>T | Splice Region (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- KIF16B | c.961G>C p.D321H | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIRREL3 | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.804); called by muse, mutect2
- KLHL32 | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- KLHL33 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KLHL38 | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2
- KMT2C | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- KRTAP4-8 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2
- LILRA4 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- LPCAT3 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2
- LRCH2 | c.2243T>A p.V748D | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- LRP1B | c.5690G>T p.S1897I | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2
- LRRC53 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- LRRC66 | c.1486G>T p.G496W | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MACF1 | c.9020A>T p.E3007V | Missense Mutation (SNP) | VAF 10/273 reads (4%) | called by muse, mutect2
- MAGEA8 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.933); called by muse, mutect2
- MAGT1 | c.806C>A p.T269K (on ENST00000618282 / NM_001367916.1; = p.T301K on NM_032121.5) | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- MATN2 | c.1004G>T p.C335F | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- MEIS2 | c.977G>T p.W326L (on ENST00000561208 / NM_170675.5; = p.W313L on NM_002399.3) | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, varscan2
- MFN1 | c.536G>T p.S179I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MFSD1 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- MIA3 | c.917A>G p.E306G | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- MMP10 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MOCOS | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- MRC1 | c.2112A>C p.T704= | Splice Region (SNP) | VAF 40/497 reads (8%) | called by muse, mutect2
- MRC1 | c.4073C>T p.P1358L | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- MS4A4A | c.692C>A p.A231E | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2
- MTRNR2L6 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 18/193 reads (9%) | PolyPhen benign (0.3); called by muse, mutect2
- MUC6 | c.3512G>T p.G1171V | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2
- MYH13 | c.2459A>G p.Y820C | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- MYH2 | c.3391G>T p.E1131* | Nonsense Mutation (SNP) | VAF 36/456 reads (8%) | called by muse, mutect2
- MYO16 | c.4025C>T p.T1342I | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- MYO5B | c.798T>A p.C266* | Nonsense Mutation (SNP) | VAF 19/534 reads (4%) | called by muse, mutect2
- MYOC | c.454C>A p.L152M | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NAALADL2 | c.1719A>G p.I573M | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2
- NCOA6 | c.5210G>T p.R1737L | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- NME8 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.325); called by muse, mutect2
- NTRK3 | c.2434C>G p.Q812E (on ENST00000360948 / NM_001012338.2; = p.Q798E on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2
- NUMBL | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OPRK1 | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR10A4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.013); called by muse, mutect2
- OR11H6 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- OR2T4 | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 49/657 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); called by muse, mutect2
- OR5T3 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.204); called by muse, mutect2
- OR6X1 | c.528C>G p.Y176* | Nonsense Mutation (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- OR8B12 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- OR8B8 | c.838A>T p.T280S | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.155); called by muse, mutect2
- PCDHA5 | c.842G>T p.S281I | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.34); called by muse, mutect2
- PDE3A | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- PDGFRB | c.1449G>A p.W483* | Nonsense Mutation (SNP) | VAF 28/430 reads (7%) | called by muse, mutect2
- PDS5B | c.2311G>C p.G771R | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PFKFB3 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 30/298 reads (10%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- PGLYRP2 | c.947G>T p.S316I | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PHF7 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.186); called by muse, mutect2
- PLCL2 | c.2298T>A p.F766L (on ENST00000615277 / NM_001144382.2; = p.F640L on NM_015184.5) | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- PLEKHG4 | c.3139G>T p.G1047W | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLG | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- PLP2 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- POTEC | c.1229A>G p.D410G | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, varscan2
- PPBP | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.22); called by muse, mutect2
- PPP1R12B | c.2452G>T p.D818Y | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- PRAMEF15 | c.1030C>G p.Q344E | Missense Mutation (SNP) | VAF 65/829 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- PRPF40A | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- PRR16 | c.565C>A p.H189N (on ENST00000407149 / NM_001300783.2; = p.H166N on NM_016644.2) | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.805); called by muse, mutect2
- PRXL2B | c.246G>T p.Q82H (on ENST00000444521; = p.Q52H on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); called by muse, mutect2
- PSG7 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); called by muse, mutect2
- PTCRA | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PXDNL | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 44/565 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2
- RALYL | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 27/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- RCC1L | c.1259A>T p.K420M | Missense Mutation (SNP) | VAF 29/380 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2
- RNF165 | c.485G>T p.W162L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- RP1 | c.3071G>T p.G1024V | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RSAD2 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- RTL5 | c.1065C>A p.H355Q | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); called by muse, mutect2
- RTN4IP1 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- RYR3 | c.2767T>A p.S923T | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SALL1 | c.3428T>G p.F1143C | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SATL1 | c.1273G>T p.V425L (on ENST00000395409; = p.V612L on NM_001012980.2) | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SCN1A | c.2175A>T p.E725D (on ENST00000303395 / NM_001202435.3; = p.E714D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2
- SCN8A | c.1970C>A p.S657Y | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SDCCAG8 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); called by muse, mutect2
- SDE2 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.088); called by muse, mutect2
- SEC23A | c.2176C>T p.Q726* | Nonsense Mutation (SNP) | VAF 24/466 reads (5%) | called by muse, mutect2
- SEPTIN14 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 23/337 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2
- SH3RF3 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SI | c.1114G>T p.V372L | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- SIGLEC5 | c.1519G>T p.G507W | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SIRPB1 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC16A2 | c.863A>T p.Q288L | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2
- SLC2A7 | c.629T>A p.L210Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- SLC6A14 | c.929A>T p.E310V | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SLC7A5 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 31/387 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- SMYD4 | c.995G>T p.R332M | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); called by muse, mutect2
- SNX6 | c.1204-1G>T p.X402_splice (on ENST00000652385; = p.X274_splice on NM_021249.5) | Splice Site (SNP) | VAF 20/360 reads (6%) | called by muse, mutect2
- SOWAHA | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOX7 | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- SPATA31A1 | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 35/973 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPEG | c.3563C>G p.P1188R | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPPL2C | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SPTA1 | c.5027G>A p.S1676N | Missense Mutation (SNP) | VAF 50/518 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2
- SPTB | c.2851G>T p.D951Y | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- STIM1 | c.741C>A p.D247E | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- SYNE1 | c.13683G>T p.L4561F (on ENST00000367255 / NM_182961.4; = p.L4490F on NM_033071.3) | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- SYT2 | c.1142C>A p.T381K | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2
- SYT9 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2
- TARS2 | c.1659G>T p.Q553H | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TDRD12 | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 13/396 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.254); called by muse, mutect2
- TENT4B | c.566G>T p.R189L (on ENST00000561678 / NM_001365323.2; = p.R174L on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.034); called by mutect2, varscan2
- TKTL1 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); called by muse, mutect2
- TLN1 | c.7000-1G>T p.X2334_splice | Splice Site (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- TLR7 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM200A | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- TMEM272 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); called by muse, mutect2
- TNS1 | c.4247C>G p.A1416G | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2
- TOP2A | c.2566A>T p.I856F | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAV13-2 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM77 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRPC1 | c.1174G>A p.A392T (on ENST00000476941 / NM_001251845.2; = p.A358T on NM_003304.4) | Missense Mutation (SNP) | VAF 20/335 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2
- TTBK2 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 25/412 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); called by muse, mutect2
- TTC27 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- TTN | c.96070G>A p.G32024S (on ENST00000591111; = p.G24600S on NM_003319.4) | Missense Mutation (SNP) | VAF 13/127 reads (10%) | PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.31906G>T p.A10636S (on ENST00000591111; = p.A9709S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | PolyPhen benign (0.015); called by muse, mutect2
- TTN | c.10039A>G p.I3347V (on ENST00000591111; = p.I3301V on NM_003319.4) | Missense Mutation (SNP) | VAF 21/595 reads (4%) | PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.2984G>A p.S995N (on ENST00000591111; = p.S949N on NM_003319.4) | Missense Mutation (SNP) | VAF 27/321 reads (8%) | PolyPhen benign (0); called by muse, mutect2
- TTN | c.2235G>T p.K745N (on ENST00000591111; = p.K699N on NM_003319.4) | Missense Mutation (SNP) | VAF 41/461 reads (9%) | PolyPhen benign (0.079); called by muse, mutect2
- TYR | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 15/492 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); called by muse, mutect2
- UBR4 | c.5891A>T p.E1964V | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- UCN | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- UNC5C | c.1020C>A p.C340* | Nonsense Mutation (SNP) | VAF 19/214 reads (9%) | called by muse, mutect2
- UNC80 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2
- UNC80 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2
- USH2A | c.8982G>T p.W2994C | Missense Mutation (SNP) | VAF 17/482 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); called by muse, mutect2
- USP35 | c.726G>T p.L242F | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- VLDLR | c.848T>G p.F283C | Missense Mutation (SNP) | VAF 53/669 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- VSIG4 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 17/452 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.654); called by muse, mutect2
- VSTM5 | c.506T>G p.V169G | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2
- WASHC5 | c.3070A>C p.N1024H | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- WWC1 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.113); called by muse, mutect2
- WWC1 | c.1827G>T p.Q609H | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.073); called by muse, mutect2
- XYLB | c.141-2A>T p.X47_splice | Splice Site (SNP) | VAF 15/211 reads (7%) | called by muse, mutect2
- YARS1 | c.592T>A p.Y198N | Missense Mutation (SNP) | VAF 20/385 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ZC3H18 | c.1619G>C p.R540T | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF217 | c.2513A>C p.Q838P | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- ZNF25 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2
- ZNF382 | c.26T>G p.F9C | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ZNF467 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); called by muse, mutect2
- ZNF486 | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- ZNF551 | c.1514G>A p.C505Y | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF615 | c.1546G>T p.E516* | Nonsense Mutation (SNP) | VAF 17/458 reads (4%) | called by muse, mutect2
- ZNF804A | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- ZSCAN9 | c.333G>T p.W111C | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACACB | c.5694G>A p.G1898= | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- ACP4 | c.501G>T p.R167= | Silent (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- ACSM1 | c.765G>T p.R255= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as rs1416042059; called by muse, mutect2, varscan2
- ACSM1 | c.84C>A p.R28= | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- ADAMTSL1 | c.2406A>C p.T802= | Silent (SNP) | VAF 24/460 reads (5%) | called by muse, mutect2
- ADAMTSL3 | c.930A>T p.P310= | Silent (SNP) | VAF 13/324 reads (4%) | called by muse, mutect2
- ADCY8 | c.126G>T p.V42= | Silent (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- AIFM3 | c.1515G>A p.A505= | Silent (SNP) | VAF 16/386 reads (4%) | catalogued as rs1345804000; called by muse, mutect2
- AKAP4 | c.948G>A p.Q316= | Silent (SNP) | VAF 16/413 reads (4%) | called by muse, mutect2
- ARFGEF2 | c.4824C>G p.S1608= | Silent (SNP) | VAF 36/526 reads (7%) | called by muse, mutect2
- ARHGAP20 | c.3384G>A p.L1128= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV52821526; called by muse, mutect2
- ARHGAP31 | c.1566G>C p.L522= | Silent (SNP) | VAF 10/305 reads (3%) | called by muse, mutect2
- B3GALT1 | c.306G>T p.G102= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- BABAM2 | c.120A>G p.L40= | Silent (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- BIVM-ERCC5 | c.2325G>A p.V775= | Silent (SNP) | VAF 24/378 reads (6%) | called by muse, mutect2
- BRINP3 | c.1629G>A p.K543= | Silent (SNP) | VAF 12/215 reads (6%) | catalogued as rs983592772, COSV66523943; called by muse, mutect2
- BTNL9 | c.1227G>T p.G409= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- C4orf54 | c.3168C>T p.G1056= | Silent (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- CALY | c.45C>T p.D15= | Silent (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- CASKIN1 | c.3741C>A p.S1247= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV58214851; called by muse, mutect2
- CCDC154 | c.945C>A p.L315= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV66735524; called by muse, mutect2, varscan2
- CHRDL1 | c.1326G>A p.L442= (on ENST00000372045; = p.L448= on NM_145234.4) | Silent (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.300C>A p.T100= | Silent (SNP) | VAF 14/469 reads (3%) | called by muse, mutect2
- CNTNAP5 | c.1284G>C p.V428= | Silent (SNP) | VAF 13/268 reads (5%) | called by muse, mutect2
- COL5A2 | c.411A>T p.P137= | Silent (SNP) | VAF 48/569 reads (8%) | called by muse, mutect2
- CPO | c.1011G>C p.V337= | Silent (SNP) | VAF 42/598 reads (7%) | called by muse, mutect2
- CREBBP | c.267G>A p.V89= | Silent (SNP) | VAF 19/287 reads (7%) | called by muse, mutect2
- CSMD2 | c.1941C>A p.T647= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- CTDP1 | c.1659G>A p.E553= | Silent (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- DAB2 | c.315T>C p.I105= | Silent (SNP) | VAF 20/512 reads (4%) | called by muse, mutect2
- DGKI | c.150G>C p.A50= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ENOX1 | c.1251C>G p.V417= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV54906094; called by muse, mutect2
- FAT4 | c.13479G>T p.L4493= | Silent (SNP) | VAF 15/275 reads (5%) | called by muse, mutect2
- FRG2 | c.678C>T p.S226= | Silent (SNP) | VAF 12/316 reads (4%) | catalogued as COSV66459946; called by muse, mutect2
- FSIP2 | c.18336C>A p.I6112= | Silent (SNP) | VAF 9/177 reads (5%) | catalogued as COSV58091170; called by muse, mutect2
- GAD2 | c.111G>T p.T37= | Silent (SNP) | VAF 23/280 reads (8%) | catalogued as COSV99393268; called by muse, mutect2
- GAD2 | c.192G>A p.P64= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- GFRA1 | c.672G>A p.R224= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- GNAI2 | c.60C>T p.D20= | Silent (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2
- GPR139 | c.678C>A p.T226= | Silent (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- GRK1 | c.1383G>A p.R461= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
- HPS3 | c.1977C>T p.A659= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- IL17D | c.588C>T p.N196= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs754420264; called by mutect2, varscan2
- ITGAX | c.1347C>A p.V449= | Silent (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
- JAG2 | c.180G>C p.G60= | Silent (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- KATNAL2 | c.1296C>A p.I432= (on ENST00000356157 / NM_001353899.1; = p.I360= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/254 reads (5%) | called by muse, mutect2
- KCNH4 | c.1947G>T p.L649= | Silent (SNP) | VAF 17/443 reads (4%) | called by muse, mutect2
- KCNK13 | c.768C>G p.L256= | Silent (SNP) | VAF 18/367 reads (5%) | catalogued as COSV56416987; called by muse, mutect2
- KCNMB1 | c.289C>A p.R97= | Silent (SNP) | VAF 37/477 reads (8%) | catalogued as COSV51131212; called by muse, mutect2
- KEL | c.1374C>A p.P458= | Silent (SNP) | VAF 20/426 reads (5%) | called by muse, mutect2
- KIFAP3 | c.453G>T p.R151= | Silent (SNP) | VAF 16/215 reads (7%) | called by muse, mutect2
- KLHDC4 | c.810G>T p.L270= | Silent (SNP) | VAF 17/201 reads (8%) | catalogued as rs759903960; called by muse, mutect2
- LPCAT3 | c.129G>T p.R43= | Silent (SNP) | VAF 20/305 reads (7%) | called by muse, mutect2
- LPIN1 | c.84A>T p.S28= | Silent (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- LRFN5 | c.1920C>A p.S640= | Silent (SNP) | VAF 24/542 reads (4%) | catalogued as COSV53250497; called by muse, mutect2
- LRRC37A3 | c.4449C>G p.S1483= | Silent (SNP) | VAF 105/750 reads (14%) | called by muse, mutect2, varscan2
- MDC1 | c.4098T>G p.T1366= | Silent (SNP) | VAF 29/213 reads (14%) | catalogued as rs758821594; called by muse, mutect2, varscan2
- MPL | c.519C>A p.P173= | Silent (SNP) | VAF 9/282 reads (3%) | called by muse, mutect2
- MYO7A | c.3331C>T p.L1111= | Silent (SNP) | VAF 28/293 reads (10%) | called by muse, mutect2
- MYO7A | c.4314C>T p.A1438= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, varscan2
- NID1 | c.1575G>T p.V525= | Silent (SNP) | VAF 38/302 reads (13%) | called by muse, mutect2, varscan2
- OR13G1 | c.135C>A p.A45= | Silent (SNP) | VAF 34/424 reads (8%) | catalogued as COSV62945336; called by muse, mutect2
- OR1L8 | c.45C>A p.L15= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- OR2T1 | c.654C>A p.A218= | Silent (SNP) | VAF 24/372 reads (6%) | catalogued as rs1452475899; called by muse, mutect2
- OR2T4 | c.183G>T p.V61= | Silent (SNP) | VAF 51/650 reads (8%) | called by muse, mutect2
- OR4Q2 | c.795G>A p.V265= | Silent (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- OR51B5 | c.372C>T p.I124= | Silent (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- OR51E2 | c.843G>T p.L281= | Silent (SNP) | VAF 36/636 reads (6%) | called by muse, mutect2
- OR52R1 | c.684G>T p.V228= | Silent (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- OR5AR1 | c.553T>C p.L185= | Silent (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- OR5J2 | c.732C>T p.H244= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as rs1387458216, COSV56622405; called by muse, mutect2
- OR6V1 | c.816G>T p.V272= | Silent (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- OTOF | c.777G>T p.T259= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- OVCH1 | c.2586G>A p.R862= | Silent (SNP) | VAF 21/308 reads (7%) | called by muse, mutect2
- PCDHB16 | c.684C>A p.V228= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV53372269; called by muse, mutect2
- PCDHGA3 | c.1374C>A p.S458= | Silent (SNP) | VAF 29/281 reads (10%) | catalogued as COSV53915304; called by muse, mutect2, varscan2
- PDE8B | c.487C>A p.R163= | Silent (SNP) | VAF 26/464 reads (6%) | catalogued as COSV53736199, COSV99367306; called by muse, mutect2
- PLD5 | c.1011G>A p.K337= (on ENST00000442594; = p.K275= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/215 reads (6%) | called by muse, mutect2
- PLG | c.2086C>A p.R696= | Silent (SNP) | VAF 17/316 reads (5%) | catalogued as rs144869703, COSV57518417; called by muse, mutect2
- PLS3 | c.1359G>T p.L453= | Silent (SNP) | VAF 8/180 reads (4%) | catalogued as COSV56779084; called by muse, mutect2
- PPIAL4G | c.69A>G p.K23= | Silent (SNP) | VAF 25/742 reads (3%) | called by muse, mutect2
- PPM1B | c.606G>T p.L202= | Silent (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- PPP2R3C | c.897A>T p.S299= | Silent (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- PTPRD | c.1245A>G p.Q415= | Silent (SNP) | VAF 13/285 reads (5%) | catalogued as rs1413029691; called by muse, mutect2
- PXDNL | c.876C>A p.I292= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- RERGL | c.552C>A p.P184= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- RPS6KL1 | c.309T>A p.I103= | Silent (SNP) | VAF 28/346 reads (8%) | called by muse, mutect2
- SCUBE1 | c.255G>A p.G85= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- SERPINA6 | c.363C>A p.T121= | Silent (SNP) | VAF 28/426 reads (7%) | catalogued as COSV100448099; called by muse, mutect2
- SERPINB5 | c.1023C>A p.I341= | Silent (SNP) | VAF 24/328 reads (7%) | catalogued as COSV66975299; called by muse, mutect2
- SLC22A6 | c.549C>A p.P183= | Silent (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- SLC28A1 | c.1651C>T p.L551= | Silent (SNP) | VAF 17/325 reads (5%) | called by muse, mutect2
- SNRPN | c.351T>A p.G117= | Silent (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- ST6GAL2 | c.207C>G p.S69= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- SUN1 | c.2079C>T p.R693= (on ENST00000405266 / NM_001367651.1; = p.R573= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as rs774990499; ClinVar: likely benign; called by muse, mutect2
- SYT6 | c.1470C>T p.I490= (on ENST00000610222 / NM_001366225.1; = p.I405= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as rs370803872; called by muse, mutect2
- TAAR8 | c.336G>T p.V112= | Silent (SNP) | VAF 14/283 reads (5%) | called by muse, mutect2
- TENT4B | c.567A>T p.R189= (on ENST00000561678 / NM_001365323.2; = p.R174= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- THBS2 | c.75G>C p.T25= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV64681193; called by muse, mutect2
- TNPO1 | c.720G>A p.R240= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- TUBB8 | c.1071A>C p.P357= | Silent (SNP) | VAF 34/772 reads (4%) | called by muse, mutect2
- VWA8 | c.99G>A p.R33= | Silent (SNP) | VAF 16/252 reads (6%) | catalogued as rs1416706321; called by muse, mutect2
- WDFY3 | c.3027A>T p.V1009= | Silent (SNP) | VAF 24/404 reads (6%) | called by muse, mutect2
- WDR45 | c.486G>T p.P162= (on ENST00000376372 / NM_001029896.2; = p.P163= on NM_007075.3) | Silent (SNP) | VAF 8/167 reads (5%) | catalogued as COSV100540262; called by muse, mutect2
- WDR6 | c.2619C>T p.P873= | Silent (SNP) | VAF 14/254 reads (6%) | catalogued as rs1266864555; called by muse, mutect2
- WNT9A | c.183G>T p.R61= | Silent (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- ZMYM3 | c.2709C>A p.P903= | Silent (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- ZNF536 | c.2187T>A p.A729= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV62832151; called by muse, mutect2
- ZNF83 | c.444A>G p.P148= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- ZNF99 | c.2106G>A p.K702= | Silent (SNP) | VAF 12/370 reads (3%) | called by muse, mutect2
- AC015802.6 | chr17:76559058 A>G | 3'Flank (SNP) | VAF 9/61 reads (15%) | catalogued as rs955924191; called by muse, mutect2, varscan2
- AC024940.1 | n.233A>G | RNA (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- AC133561.1 | n.1547C>A | RNA (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- AK2 | chr1:33008842 G>A | 3'Flank (SNP) | VAF 17/276 reads (6%) | called by muse, mutect2
- AMFR | c.*282G>A | 3'UTR (SNP) | VAF 16/150 reads (11%) | catalogued as COSV99316099; called by muse, mutect2, varscan2
- APOOP5 | n.235C>A | RNA (SNP) | VAF 17/282 reads (6%) | called by muse, mutect2
- BCAP31 | c.-44-315C>A | Intron (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- BOLL | c.*86T>A | 3'UTR (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- CASP16P | chr16:3148951 G>T | 3'Flank (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- CFAP65 | c.542+44C>T | Intron (SNP) | VAF 39/456 reads (9%) | called by muse, mutect2
- CLN3 | c.765+17G>T | Intron (SNP) | VAF 18/357 reads (5%) | called by muse, mutect2
- CTCFL | c.1841-1675G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- DHRS4L1 | n.177-478G>T | Intron (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- EFHD1 | c.302+4430G>T | Intron (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- EPB41L2 | c.2044-237G>T | Intron (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
- EPHB6 | c.1918+33G>C | Intron (SNP) | VAF 12/157 reads (8%) | called by muse, mutect2
- ERMARD | c.1521-86G>T | Intron (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- FAM205BP | n.1761C>A | RNA (SNP) | VAF 25/653 reads (4%) | called by muse, mutect2
- GH2 | c.457-70T>C | Intron (SNP) | VAF 14/207 reads (7%) | catalogued as rs1480980025; called by muse, mutect2
- GNB5 | c.628-30C>T | Intron (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- GUCY1A2 | c.1836+29802A>T | Intron (SNP) | VAF 7/157 reads (4%) | called by muse, mutect2
- IGHEP1 | n.545G>T | RNA (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- LINC00303 | n.160C>A | RNA (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- MIR520H | n.43G>T | RNA (SNP) | VAF 14/253 reads (6%) | catalogued as rs1293541872; called by muse, mutect2
- MLIP | c.613-11486C>A | Intron (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- MPRIP | c.2164-4227A>T | Intron (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- NFU1 | chr2:69437448 C>T | 5'Flank (SNP) | VAF 11/297 reads (4%) | catalogued as COSV100361142; called by muse, mutect2
- NRIP1 | c.-537-7280G>T | Intron (SNP) | VAF 17/544 reads (3%) | called by muse, mutect2
- OR10AB1P | n.687C>A | RNA (SNP) | VAF 16/210 reads (8%) | catalogued as rs1273312766; called by muse, mutect2
- PABPC1P2 | n.773G>A | RNA (SNP) | VAF 31/303 reads (10%) | called by muse, mutect2, varscan2
- PDE10A | c.106+91872A>T | Intron (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- PMPCB | c.99+60C>T | Intron (SNP) | VAF 23/189 reads (12%) | catalogued as rs971309054; called by muse, mutect2, varscan2
- RBM41 | c.928-947G>T | Intron (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
- RHOJ | c.*112C>T | 3'UTR (SNP) | VAF 8/156 reads (5%) | catalogued as rs946665280; called by muse, mutect2
- RRP7A | c.*3872C>G | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- SIGLEC12 | c.428-22G>T | Intron (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- SIRPB2 | c.859+38C>T | Intron (SNP) | VAF 19/310 reads (6%) | called by muse, mutect2
- SSPOP | n.10447C>G | RNA (SNP) | VAF 11/115 reads (10%) | catalogued as COSV100947791, COSV65131423; called by muse, mutect2
- TEX35 | c.90+37C>A | Intron (SNP) | VAF 12/284 reads (4%) | catalogued as rs1558036367; called by muse, mutect2
- TEX35 | c.586+471C>A | Intron (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- TLL1 | c.1524+983C>G | Intron (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2
- TLL1 | c.1524+984C>A | Intron (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- TMEM135 | c.*2793G>T | 3'UTR (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- TTN | c.10360+2596G>T | Intron (SNP) | VAF 11/141 reads (8%) | catalogued as COSV60218020; called by muse, mutect2
- TTN | c.10360+2595A>T | Intron (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- TUBB8P7 | n.837C>A | RNA (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- UBR7 | c.*1450G>T | 3'UTR (SNP) | VAF 11/310 reads (4%) | catalogued as rs559720048; called by muse, mutect2
- UMPS | c.*9G>T | 3'UTR (SNP) | VAF 41/617 reads (7%) | called by muse, mutect2
- XRCC5 | chr2:216107526 G>T | 5'Flank (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- ZNF971P | n.773G>T | RNA (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
